Somatic mutation profile of tumor specimen CUPP-B49D-TTM1-A (aliquot CUPP-B49D-TTM1-A-1-0-D-A82Z-47) from CCG case CUPP-B49D, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, malignant, uncertain whether primary or metastatic; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 43.6 years (15,935 days).
Specimen CUPP-B49D-TTM1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c3edc28-b633-4a92-90b1-bd70c864a58f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B49D-NT1-A (FFPE Scrolls), aliquot CUPP-B49D-NT1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67d99fdd-86cc-4000-a520-3dc9c238c5bb

The open-access MAF lists 295 somatic variants for this specimen: 207 protein-altering or splice-affecting, 66 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 66, Intron 15, Frame Shift Del 6, In Frame Del 5, Frame Shift Ins 4, 3'UTR 3, Nonsense Mutation 3, RNA 2, Translation Start Site 2, 5'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180177239, CM993607, COSV56754178; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GALNS | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs118204448, CM1410235, CM950535, COSV51938223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.748A>G p.R250G | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs149928780; called by muse, varscan2
- ABCF3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as rs532627156, COSV53048314; called by mutect2, varscan2
- ABHD12 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100195013; called by mutect2, varscan2
- AC015802.6 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as rs948169731; called by muse, mutect2, varscan2
- ADCY1 | c.2440C>T p.L814F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs938254758; called by mutect2, varscan2
- ADORA3 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs778275977; called by mutect2, varscan2
- ALPP | c.203T>A p.V68E | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756126114; called by mutect2, varscan2
- ANKS6 | c.1418A>G p.Q473R | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.968); catalogued as COSV100782314; called by muse, mutect2, varscan2
- AP2A1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs372011505; called by muse, mutect2, varscan2
- ARHGAP22 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs571846097; called by mutect2, varscan2
- ASIC3 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs150496362; called by mutect2, varscan2
- ATAD2B | c.3392C>A p.A1131E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV53202990; called by mutect2, varscan2
- AUTS2 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.784); catalogued as rs138775036; called by muse, mutect2, varscan2
- BCL9L | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs753760118; called by mutect2, varscan2
- BRD2 | c.948G>C p.M316I | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs369113238; called by muse, mutect2, varscan2
- C4orf46 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs776593810, COSV100309753; called by mutect2, varscan2
- C7orf50 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs370307866; called by mutect2, varscan2
- CASD1 | c.1162A>G p.N388D | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs116301340; called by mutect2, varscan2
- CCDC32 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367681812; called by mutect2, varscan2
- CCDC66 | c.2074A>G p.K692E (on ENST00000394672 / NM_001353147.1; = p.K658E on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1242056253; called by muse, mutect2, varscan2
- CCKBR | c.166A>G p.I56V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1230079114; called by muse, mutect2, varscan2
- CCL4 | c.210C>G p.S70R | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs546176473; called by muse, varscan2
- CCPG1 | c.1421G>A p.S474N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369329768; called by mutect2, varscan2
- CDC42BPB | c.2830C>A p.L944I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs376599246; called by mutect2, varscan2
- CDC42BPG | c.4021G>C p.D1341H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430141961; called by muse, mutect2, varscan2
- CEACAM8 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs139818691; called by mutect2, varscan2
- CEP83 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs568103955; ClinVar: uncertain significance; called by mutect2, varscan2
- CHFR | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as rs1221878184, COSV57178696; called by muse, mutect2, varscan2
- CHRNA7 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1296944199, COSV100180621; called by mutect2, varscan2
- CORO6 | c.1220A>G p.K407R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as rs556568259; called by mutect2, varscan2
- CREB3L4 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs147964019; called by mutect2, varscan2
- CYP2A6 | c.127A>C p.I43L | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs747479415; called by muse, mutect2, varscan2
- DBF4 | c.1145A>G p.Q382R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.69); catalogued as rs372736107; called by mutect2, varscan2
- DDX24 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs139389411; called by muse, mutect2, varscan2
- DES | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.333); catalogued as rs578066781; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.6184G>T p.D2062Y | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV56615016; called by mutect2, varscan2
- DNAH2 | c.8318G>A p.R2773H | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374110523; called by muse, varscan2
- DOK7 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs115883468; called by muse, mutect2, varscan2
- ECEL1 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1030034156; called by muse, mutect2, varscan2
- EFCAB8 | c.3710C>T p.A1237V | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.359); catalogued as rs1302412103; called by mutect2, varscan2
- EPPK1 | c.9496C>T p.R3166C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs1450367748; called by mutect2, varscan2
- ERBB2 | c.774C>G p.F258L | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV54078623; called by muse, mutect2, varscan2
- FAM222B | c.1402T>G p.S468A | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.53); catalogued as rs912500113; called by muse, varscan2
- FAT1 | c.9130C>A p.Q3044K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs201737827; called by mutect2, varscan2
- FAXDC2 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768397675; called by mutect2, varscan2
- FBXO41 | c.1497G>C p.E499D | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as rs377555341; called by muse, mutect2, varscan2
- FKBP6 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs1275158987; called by muse, varscan2
- FLT4 | c.3522G>C p.Q1174H | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs149299992, COSV56124897, COSV99987707; called by muse, mutect2, varscan2
- FN1 | c.5492C>T p.T1831I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs182139649; called by mutect2, varscan2
- GALNT12 | c.1583A>G p.N528S | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.197); catalogued as rs142096902; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATA6 | c.531_545del p.A179_A183del | In Frame Del (DEL) | VAF 16/57 reads (28%) | catalogued as rs777216159; called by mutect2, varscan2
- GBX2 | c.334T>C p.F112L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as rs764631873; called by muse, varscan2
- GCNT7 | c.480_481insA p.V161Sfs*13 | Frame Shift Ins (INS) | VAF 9/81 reads (11%) | catalogued as rs769784953; called by mutect2, varscan2
- GFUS | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); catalogued as rs749145675; called by mutect2, varscan2
- GLI4 | c.669G>C p.W223C | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as rs757499264; called by muse, mutect2, varscan2
- GMEB2 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as rs973542159; called by muse, mutect2, varscan2
- GPRC6A | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.372); catalogued as COSV59952434; called by muse, varscan2
- GSTA1 | c.270C>T p.A90= | Splice Region (SNP) | VAF 20/72 reads (28%) | catalogued as rs752735714; called by mutect2, varscan2
- HAUS4 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs143658941; called by muse, mutect2, varscan2
- HELZ | c.5749A>G p.S1917G | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.952); catalogued as rs952953168; called by muse, mutect2, varscan2
- HHLA1 | c.75C>G p.N25K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs993426539; called by muse, mutect2, varscan2
- HPS6 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.368); catalogued as rs1450101908, COSV54626308; called by muse, mutect2, varscan2
- ICE1 | c.4058G>C p.G1353A | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56829677; called by muse, mutect2, varscan2
- IFIT3 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs755384820; called by muse, mutect2, varscan2
- IGHG1 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.878); catalogued as rs372557334; called by muse, mutect2, varscan2
- IGSF8 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773677868; called by muse, varscan2
- IGSF9B | c.3724C>G p.P1242A | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.157); catalogued as rs1344850675; called by mutect2, varscan2
- INPP5D | c.499C>T p.R167* (on ENST00000445964 / NM_001017915.3; = p.R166* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as rs753207715, COSV64036812; called by muse, mutect2, varscan2
- IRAK1 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs199501854; called by muse, varscan2
- KANK1 | c.1393_1408del p.L465Ifs*3 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs771710809; called by pindel, varscan2
- KANSL1 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV52275332; called by muse, mutect2, varscan2
- KLHL32 | c.811A>G p.I271V | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs931837204; called by muse, varscan2
- KRTAP9-1 | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.54); catalogued as rs1182912573; called by muse, mutect2, varscan2
- LAD1 | c.483_486delinsT p.L161_V162delinsF | In Frame Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs386638482; called by pindel, varscan2*
- LAMB2 | c.4363C>T p.R1455W | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901971113, COSV59734847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIG1 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs745950562, COSV54389778; called by mutect2, varscan2
- LPIN2 | c.658_660del p.H220del | In Frame Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs761910090; called by mutect2, pindel, varscan2
- LRRC14B | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751807446; called by muse, varscan2
- LSG1 | c.1880C>G p.A627G | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs370741277; called by muse, mutect2, varscan2
- LZTR1 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs375451574; called by muse, mutect2, varscan2
- MAP10 | c.1438_1440del p.P480del | In Frame Del (DEL) | VAF 14/101 reads (14%) | catalogued as rs765072281; called by pindel, varscan2
- MAPK13 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1397181580; called by mutect2, varscan2
- MAST3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs1410386265, COSV53218937; called by muse, mutect2, varscan2
- MBNL3 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768478546; called by muse, mutect2, varscan2
- MCF2L | c.3242T>C p.V1081A (on ENST00000375608; = p.V1049A on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as rs766665721; called by muse, mutect2, varscan2
- MGAM | c.2012G>T p.R671M | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs370644495; called by muse, mutect2, varscan2
- MRPL18 | c.378G>C p.E126D | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV99277636; called by muse, mutect2, varscan2
- MUC2 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs776722961; called by muse, mutect2, varscan2
- MUC22 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT tolerated (0.63); catalogued as rs200777418; called by muse, varscan2
- MYLK3 | c.782G>C p.G261A | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1174433944, COSV67366535; called by muse, mutect2, varscan2
- NBPF10 | c.2065C>A p.P689T | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs200946158, COSV61659816; called by muse, mutect2, varscan2
- NPHP3 | c.3290A>G p.N1097S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157229330; called by muse, mutect2, varscan2
- NR5A2 | c.119del p.V40Afs*35 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs748596855; called by mutect2, pindel, varscan2
- NRG1 | c.205A>C p.K69Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs747804470; called by mutect2, varscan2
- NUDT16L1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs1046143984; called by mutect2, varscan2
- NYAP1 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs760779356, COSV55720835; called by muse, varscan2
- OCM | c.124A>C p.N42H | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs371444161; called by muse, mutect2, varscan2
- OR2W3 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100831867; called by muse, mutect2, varscan2
- OR6A2 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.747); catalogued as rs375343517; called by mutect2, varscan2
- OS9 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs139138685; called by mutect2, varscan2
- OXCT2 | c.1422C>A p.D474E | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs751621137; called by mutect2, varscan2
- PDZD11 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV52103808; called by muse, mutect2, varscan2
- PHF14 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs201555495; called by mutect2, varscan2
- PIGS | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1211387111; called by muse, mutect2, varscan2
- PIP4K2A | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs527968606; called by muse, mutect2, varscan2
- PNCK | c.121G>A p.V41M (on ENST00000340888 / NM_001366975.1; = p.V124M on NM_001039582.3) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61742464; called by muse, mutect2, varscan2
- POLE4 | c.15_20del p.AA6_?7 | Translation Start Site (DEL) | VAF 4/18 reads (22%) | catalogued as rs528770146; called by mutect2, varscan2
- POP4 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1047470546; called by muse, mutect2, varscan2
- PSG1 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs746821988, COSV99740486; called by muse, mutect2, varscan2
- PSG7 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs184987448, COSV68446460, COSV68446870; called by mutect2, varscan2
- PTK7 | c.1904C>G p.T635S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761818353; called by mutect2, varscan2
- RAB11FIP3 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149968783; called by muse, mutect2, varscan2
- RAB3IL1 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.968); catalogued as rs139628915; called by mutect2, varscan2
- RAI1 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377314203; ClinVar: uncertain significance; called by muse, varscan2
- RGS12 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs200383596; called by muse, mutect2, varscan2
- RHBDL3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.862); catalogued as rs762346732, COSV99283926; called by mutect2, varscan2
- RICTOR | c.3404C>T p.T1135M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371456052, COSV57119597; called by mutect2, varscan2
- RPGRIP1L | c.3401A>C p.D1134A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1387709465; called by muse, varscan2
- SAP130 | c.2378T>C p.I793T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs374179924; called by mutect2, varscan2
- SCML2 | c.1705G>T p.V569F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV52621461; called by mutect2, varscan2
- SCN4A | c.3608T>C p.V1203A | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1009902432, COSV71126639; called by muse, mutect2, varscan2
- SEMA7A | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs775757047; called by mutect2, varscan2
- SGCE | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs116324366; called by mutect2, varscan2
- SH3TC1 | c.3338T>A p.F1113Y | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs377306484; called by mutect2, varscan2
- SHCBP1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs779702179, COSV57650892; called by muse, mutect2, varscan2
- SLC44A4 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs774489026, COSV57666541; called by muse, mutect2, varscan2
- SLC46A2 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs376496916; called by mutect2, varscan2
- SLC52A3 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as rs145194879; called by muse, varscan2
- SNAPC4 | c.2588G>C p.S863T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs753444527; called by muse, mutect2, varscan2
- SPEG | c.7943G>A p.G2648D | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.239); catalogued as rs773671133; called by mutect2, varscan2
- STAU2 | c.1390A>G p.I464V (on ENST00000524300 / NM_001164380.2; = p.I432V on NM_014393.2) | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs562806983; called by muse, varscan2
- SYCE1 | c.212A>G p.N71S (on ENST00000343131 / NM_001143764.3; = p.N35S on NM_130784.3) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1213378771; called by muse, varscan2
- TACC2 | c.4045A>G p.T1349A | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141137444; called by muse, mutect2, varscan2
- TMEM132B | c.2203G>A p.V735M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs61748706; called by mutect2, varscan2
- TP53 | c.97-10_97-1dup p.S33Pfs*13 | Frame Shift Ins (INS) | VAF 12/62 reads (19%) | catalogued as COSV53359775, COSV99475020; called by mutect2, varscan2
- TRABD2A | c.1204C>G p.L402V (on ENST00000409520 / NM_001277053.2; = p.L353V on NM_001080824.3) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs548830847, COSV52878407; called by mutect2, varscan2
- TRRAP | c.4879G>A p.G1627S (on ENST00000359863 / NM_001244580.1; = p.G1609S on NM_003496.3) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.033); catalogued as rs782510081, COSV100723238; called by muse, varscan2
- TTC7A | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.302); catalogued as COSV55409146; called by muse, mutect2, varscan2
- TTLL11 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373568909; called by mutect2, varscan2
- TTN | c.27595C>T p.R9199C (on ENST00000591111; = p.R8272C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | PolyPhen probably damaging (0.982); catalogued as rs751958797, COSV100638442; called by mutect2, varscan2
- VSIG2 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.035); catalogued as COSV52519653; called by muse, mutect2, varscan2
- WNK2 | c.3635A>G p.K1212R | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs142000432; called by muse, mutect2, varscan2
- ZDHHC14 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV63075193; called by muse, mutect2, varscan2
- ZNF493 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as rs756706731, COSV62749172; called by mutect2, varscan2
- ZNF503 | c.1894C>T p.L632F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as rs770037190; called by mutect2, varscan2
- ZNF512B | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs765901997; called by muse, mutect2, varscan2
- ZNF598 | c.429G>C p.E143D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs190028351; called by muse, mutect2, varscan2
- ZNF750 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs761450879, COSV53959396; called by mutect2, varscan2
- ZNF79 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1207686561; called by muse, mutect2, varscan2
- ZNF804B | c.2062G>T p.V688F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.31); catalogued as rs150806475; called by mutect2, varscan2
- AOPEP | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQP6 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- ARG1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by mutect2, varscan2
- ARL9 | c.121_170delinsGAAAAGCAAGAGAAGCAGGAGAGGAGAAAGGGAAAAGAGAAAGAGGAAAA p.K41_R57delinsEKQEKQERRKGKEKEEK | Missense Mutation (ONP) | VAF 5/59 reads (8%) | called by mutect2*, pindel
- ATF2 | c.237_238del p.C79* | Nonsense Mutation (DEL) | VAF 8/62 reads (13%) | called by pindel, varscan2
- C3orf38 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CA12 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.005); called by mutect2, varscan2
- CBFA2T3 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, varscan2
- CCDC168 | c.7674A>T p.K2558N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.636); called by mutect2, varscan2
- CCDC9B | c.810G>C p.K270N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CEP95 | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLK1 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); called by mutect2, varscan2
- COL27A1 | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- COL4A3 | c.75del p.A26Qfs*67 | Frame Shift Del (DEL) | VAF 1/20 reads (5%) | called by mutect2, varscan2*
- DCAF5 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- DCDC2 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- DNAJB8 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DSG3 | c.2303_2309delinsTTGG p.T768_H770delinsIG | In Frame Del (DEL) | VAF 22/61 reads (36%) | called by pindel, varscan2*
- FOS | c.443A>T p.K148M | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR84 | c.762T>G p.I254M | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- GRIK3 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- KNTC1 | c.2759C>T p.P920L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by mutect2, varscan2
- KRT6C | c.1223C>G p.A408G | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- KRT76 | c.1706dup p.R570Qfs*3 | Frame Shift Ins (INS) | VAF 26/174 reads (15%) | called by pindel, varscan2
- LPIN3 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- LRRC20 | c.520A>T p.M174L (on ENST00000355790 / NM_207119.3; = p.M118L on NM_018205.4) | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- LRRC31 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by mutect2, varscan2
- MACF1 | c.8767G>A p.E2923K | Missense Mutation (SNP) | VAF 8/89 reads (9%) | called by mutect2, varscan2
- MGA | c.7393dup p.T2465Nfs*6 (on ENST00000219905 / NM_001164273.1; = p.T2256Nfs*6 on NM_001080541.2) | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- NLK | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NOXRED1 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.123); called by mutect2, varscan2
- NQO1 | c.355_358del p.R119Cfs*3 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by pindel, varscan2*
- ORAI2 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by mutect2, varscan2
- OSBPL7 | c.917T>G p.L306R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by mutect2, varscan2
- OSBPL7 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.916); called by mutect2, varscan2
- PDZRN4 | c.1523T>C p.L508S (on ENST00000402685 / NM_001164595.2; = p.L250S on NM_013377.4) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by mutect2, varscan2
- PRSS8 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, varscan2
- SEMA4A | c.2071T>A p.F691I | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- SH3BP5 | c.271del p.I91Lfs*69 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- SLF2 | c.1757C>G p.S586C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- SPAG6 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPRR4 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); called by mutect2, varscan2
- ST3GAL3 | c.351C>G p.F117L (on ENST00000361392 / NM_174964.4; = p.F102L on NM_006279.5) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- STING1 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TERF2IP | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- TMEM134 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFRSF10A | c.481T>G p.L161V | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TNS3 | c.2183A>G p.N728S | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TOMM70 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TOP3B | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TRHDE | c.982T>C p.S328P | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- TRIM24 | c.2200G>T p.D734Y (on ENST00000343526 / NM_015905.3; = p.D700Y on NM_003852.4) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by mutect2, varscan2
- TRIM66 | c.136del p.R46Gfs*9 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by pindel, varscan2
- TTN | c.76894C>G p.P25632A (on ENST00000591111; = p.P18208A on NM_003319.4) | Missense Mutation (SNP) | VAF 17/101 reads (17%) | PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ZNF443 | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCA2 | c.3417G>A p.E1139= (on ENST00000614293; = p.E1109= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs1455951280; called by mutect2, varscan2
- ABL1 | c.3045C>G p.T1015= | Silent (SNP) | VAF 38/157 reads (24%) | catalogued as rs377034573; called by muse, mutect2, varscan2
- ALAD | c.288C>T p.S96= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs146076728; called by muse, mutect2, varscan2
- ALPL | c.1287G>A p.E429= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1375819603, COSV100876323; called by muse, mutect2, varscan2
- ARID5B | c.1425A>G p.Q475= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs1440654186; called by muse, mutect2, varscan2
- C16orf71 | c.777G>A p.S259= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs375519353; called by mutect2, varscan2
- CALD1 | c.1080A>G p.K360= | Silent (SNP) | VAF 61/306 reads (20%) | catalogued as rs529198474, COSV62652232; ClinVar: likely benign; called by muse, varscan2
- CATSPERD | c.2043C>T p.F681= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs747231498; called by muse, mutect2, varscan2
- CBARP | c.765G>C p.A255= (on ENST00000382477; = p.A235= on NM_152769.3) | Silent (SNP) | VAF 20/62 reads (32%) | called by mutect2, varscan2
- CDK12 | c.3336T>C p.N1112= | Silent (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- CDK5R2 | c.579C>T p.F193= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs769669157, COSV56937486; called by muse, mutect2, varscan2
- CNTN1 | c.2604C>T p.L868= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs145610308; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP27C1 | c.642A>G p.L214= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as COSV100079773; called by muse, mutect2, varscan2
- DHX37 | c.117G>A p.T39= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1365607310; called by muse, mutect2, varscan2
- DOCK11 | c.1005G>A p.Q335= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs149921668; called by mutect2, varscan2
- EP300 | c.444G>A p.T148= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as rs376779611; ClinVar: likely benign; called by muse, mutect2, varscan2
- ERCC4 | c.2466G>A p.Q822= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs757316495; called by mutect2, varscan2
- FAM177B | c.228C>T p.S76= | Silent (SNP) | VAF 9/59 reads (15%) | called by mutect2, varscan2
- FAT1 | c.3993T>C p.G1331= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs781000985; called by muse, mutect2, varscan2
- FBRSL1 | c.2520C>G p.P840= | Silent (SNP) | VAF 75/199 reads (38%) | catalogued as rs1033158590, COSV99904723; called by muse, mutect2, varscan2
- FIZ1 | c.1096C>T p.L366= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as rs763086872; called by mutect2, varscan2
- FOXQ1 | c.543G>A p.L181= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs141889157; called by mutect2, varscan2
- GAD1 | c.1287G>A p.Q429= | Silent (SNP) | VAF 16/92 reads (17%) | called by mutect2, varscan2
- GPR162 | c.1413T>C p.A471= (on ENST00000311268 / NM_019858.2; = p.A187= on NM_014449.2) | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs1555120263; called by muse, mutect2, varscan2
- IGHD | c.618G>T p.V206= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs368130609; called by muse, mutect2, varscan2
- IGKV3-11 | c.93G>T p.L31= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs376010585; called by mutect2, varscan2
- INSRR | c.3066G>A p.R1022= | Silent (SNP) | VAF 11/98 reads (11%) | called by mutect2, varscan2
- IRAK1 | c.1161C>A p.T387= | Silent (SNP) | VAF 47/87 reads (54%) | catalogued as rs367697342; called by muse, mutect2, varscan2
- KANK3 | c.930G>A p.E310= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs1019359766; called by mutect2, varscan2
- KIAA1328 | c.1440T>C p.D480= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs373485197, COSV99693355; called by mutect2, varscan2
- KIF21A | c.4983C>T p.I1661= (on ENST00000361418 / NM_001378440.1; = p.I1648= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs151210288; called by mutect2, varscan2
- KMT2D | c.3717C>A p.S1239= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs371257109; called by mutect2, varscan2
- MKI67 | c.9204C>T p.N3068= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs575407769, COSV64076269; called by muse, mutect2, varscan2
- MTERF1 | c.663C>T p.A221= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs752666245; called by mutect2, varscan2
- MYBPC2 | c.528G>A p.S176= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs200150398; called by muse, mutect2, varscan2
- MYH11 | c.1239A>G p.T413= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs780937971; called by muse, mutect2, varscan2
- MYH13 | c.1644C>T p.T548= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs781026958, COSV52840967; called by mutect2, varscan2
- NOX4 | c.330T>C p.V110= | Silent (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- PAX1 | c.687G>T p.A229= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as rs1027891587, COSV68272476, COSV68273101; called by mutect2, varscan2
- PCDHAC1 | c.1581C>G p.G527= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs782009999, COSV53860264; called by muse, mutect2, varscan2
- PLSCR3 | c.651C>G p.G217= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs1159859990; called by muse, varscan2
- PLXNC1 | c.1584T>C p.S528= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs375069746; called by muse, varscan2
- POLR1A | c.153C>T p.Y51= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as rs370186256; called by muse, varscan2
- PRRT4 | c.2481C>T p.R827= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as rs1276151769; called by mutect2, varscan2
- PSMC5 | c.453T>A p.I151= | Silent (SNP) | VAF 32/110 reads (29%) | called by mutect2, varscan2
- PTPRN2 | c.3021C>T p.N1007= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs962939018; called by muse, mutect2, varscan2
- QPRT | c.21G>A p.A7= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs1415426134; called by muse, mutect2, varscan2
- RAB3IL1 | c.618T>A p.A206= | Silent (SNP) | VAF 14/57 reads (25%) | called by mutect2, varscan2
- RECK | c.693A>G p.R231= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs531098629; called by muse, mutect2, varscan2
- RGMA | c.549G>T p.V183= | Silent (SNP) | VAF 28/94 reads (30%) | called by mutect2, varscan2
- SDE2 | c.378C>T p.A126= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs767370243; called by muse, mutect2, varscan2
- SEMA3A | c.939A>G p.L313= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs35078268, COSV54871579; called by mutect2, varscan2
- SLC22A14 | c.1719C>T p.H573= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs767442987; called by mutect2, varscan2
- SLC26A8 | c.2145G>A p.A715= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as rs115593646; called by muse, mutect2, varscan2
- SLC4A2 | c.1392C>T p.H464= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs766434286, COSV59655603; called by muse, varscan2
- SPN | c.915G>C p.G305= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1555489927; called by mutect2, varscan2
- SPTBN5 | c.7041G>A p.A2347= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs373431456; called by mutect2, varscan2
- TDRD15 | c.3912C>T p.I1304= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs945858373, COSV68266508; called by mutect2, varscan2
- THEMIS | c.1086G>A p.K362= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs141862398; called by mutect2, varscan2
- TRRAP | c.1221C>T p.D407= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as rs781819690; called by muse, varscan2
- TTC9B | c.433C>T p.L145= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs763712620, COSV53424175; called by mutect2, varscan2
- UGT1A6 | c.1350G>C p.P450= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs368860136, COSV100530391; called by mutect2, varscan2
- USP21 | c.1134G>A p.L378= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV99237128; called by mutect2, varscan2
- ZFYVE28 | c.825G>A p.T275= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs142497896, COSV99343044; called by mutect2, varscan2
- ZNF316 | c.855C>G p.P285= | Silent (SNP) | VAF 58/144 reads (40%) | catalogued as rs558639787; called by muse, mutect2, varscan2
- ZNF827 | c.2682T>G p.P894= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs1245865897; called by muse, mutect2, varscan2
- ABCB9 | c.2040+15G>T | Intron (SNP) | VAF 27/130 reads (21%) | catalogued as rs374106311; called by muse, mutect2, varscan2
- ADAMTS5 | c.-605G>A | 5'UTR (SNP) | VAF 38/114 reads (33%) | catalogued as rs952365805; called by muse, mutect2, varscan2
- ARHGEF28 | c.1024+18252del | Intron (DEL) | VAF 10/59 reads (17%) | catalogued as rs1301131743; called by mutect2, pindel, varscan2
- DCHS2 | n.6625A>T | RNA (SNP) | VAF 20/86 reads (23%) | called by mutect2, varscan2
- DMD | c.6438+65506A>G | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs1366983832; called by mutect2, varscan2
- DMD | c.6438+65505C>T | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs1297893148; called by mutect2, varscan2
- GRSF1 | c.357+100G>C | Intron (SNP) | VAF 11/52 reads (21%) | called by mutect2, varscan2
- GRSF1 | c.357+99C>A | Intron (SNP) | VAF 11/53 reads (21%) | called by mutect2, varscan2
- HSD17B12 | c.160+309G>A | Intron (SNP) | VAF 8/62 reads (13%) | catalogued as rs181306511; called by mutect2, varscan2
- IFT20 | c.213+246C>G | Intron (SNP) | VAF 16/107 reads (15%) | catalogued as COSV56879476; called by muse, varscan2
- IQCC | c.42+121G>A | Intron (SNP) | VAF 14/84 reads (17%) | catalogued as rs773034737; called by mutect2, varscan2
- LRRC46 | c.117-391G>A | Intron (SNP) | VAF 29/84 reads (35%) | catalogued as rs530233759; called by muse, mutect2, varscan2
- MPRIP | c.2163+3072C>T | Intron (SNP) | VAF 32/86 reads (37%) | catalogued as rs1010232113; called by muse, mutect2, varscan2
- MST1L | n.439C>T | RNA (SNP) | VAF 21/125 reads (17%) | catalogued as rs767518292; called by muse, mutect2, varscan2
- MTFP1 | c.*69A>C | 3'UTR (SNP) | VAF 11/84 reads (13%) | catalogued as rs1392347245; called by muse, varscan2
- NIBAN3 | c.*98C>T | 3'UTR (SNP) | VAF 13/59 reads (22%) | catalogued as rs904685564; called by mutect2, varscan2
- OPRM1 | c.1164+1834G>C | Intron (SNP) | VAF 14/72 reads (19%) | catalogued as rs199942335; called by mutect2, varscan2
- PSG4 | c.65-572_65-571del | Intron (DEL) | VAF 11/62 reads (18%) | catalogued as rs1440606263; called by pindel, varscan2
- TCEANC2 | c.*8131C>T | 3'UTR (SNP) | VAF 12/146 reads (8%) | called by mutect2, varscan2
- TNFRSF14 | c.305-520G>A | Intron (SNP) | VAF 32/133 reads (24%) | catalogued as COSV63188061; called by muse, mutect2, varscan2
- ZNF248 | c.-152_-150dup | 5'UTR (INS) | VAF 4/29 reads (14%) | called by mutect2, varscan2
- ZNF483 | c.412+31G>A | Intron (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100492810; called by mutect2, varscan2
